Gene-level copy-number profile of specimen HCM-CSHL-0385-C18-85A from HCMI case HCM-CSHL-0385-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 82.2 years (30,009 days).
Specimen HCM-CSHL-0385-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8703251a-9c72-4476-a248-433358f96470.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0385-C18-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/375c6b6f-6313-45aa-92a8-40b19479a4b1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 8,307; copy number 2: 42,037; copy number 3: 7,129; copy number 4: 841; copy number 5: 595.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,290,071–12,318,316, 2 genes: DEFB131D, DEFB130A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 595 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:87,250–397,559, 13 genes, copy number 5: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, NRSN2-AS1, SOX12, NRSN2, TRIB3.
- chr20:472,498–2,524,702, 58 genes, copy number 5: CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2, SLC52A3, FAM110A, RPS10P5, ANGPT4, RSPO4, AL110114.1, PSMF1, ACTG1P3, TMEM74B, AL031665.1, C20orf202, RAD21L1, SNPH, SDCBP2, AL136531.2, AL136531.3, SDCBP2-AS1, AL136531.1, FKBP1A, MIR6869, NSFL1C, SIRPB2, AL049634.1, RNU6-917P, SIRPD, AL049634.2, SIRPB1, AL049634.3, SIRPG, SIRPG-AS1, SIRPB3P, RN7SL561P, AL109809.3, AL109809.2, AL109809.4, CKAP2LP1, AL109809.1, AL117335.1, SIRPA, PDYN-AS1, PDYN, RPL7P2, STK35, AL359916.1, AL121899.4, AL121899.1, AL121899.2, TGM3, TGM6, Y_RNA, SNRPB, AL049650.1, ZNF343.
- chr20:5,114,953–5,929,318, 20 genes, copy number 5: PCNA, AL121924.1, CDS2, UBE2D3P1, PROKR2, AL121757.2, RNA5-8SP7, AL121757.3, LINC00658, AL121757.1, LINC00654, LINC01729, RPS18P1, AL109935.1, GPCPD1, EIF4EP1, SHLD1, RNU1-55P, CHGB, KANK1P1.
- chr20:6,200,989–6,780,246, 7 genes, copy number 5: TARDBPP1, AL109618.1, AL109618.2, AL109618.3, CASC20, LINC01713, BMP2.
- chr20:25,762,384–32,585,074, 88 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:32,690,180–33,111,751, 13 genes, copy number 5: BAK1P1, COMMD7, DNMT3B, MAPRE1, AL035071.2, AL035071.1, EFCAB8, SUN5, BPIFB2, BPIFB6, PUDPP3, BPIFB3, BPIFB4.
- chr20:34,872,146–36,270,918, 59 genes, copy number 5 (within-gene range 4–5): ACSS2, GSS, MYH7B, MIR499A, MIR499B, TRPC4AP, RNU6-407P, EDEM2, AL135844.1, PROCR, AL356652.1, RNA5SP483, MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1, GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1, PHF20, COX7BP2, Y_RNA, HIGD1AP16, RNU4-40P, RNU6-937P, SCAND1, CNBD2, NORAD, AL035420.1, AL035420.3, HMGB3P2, AL035420.2, EPB41L1, AL121895.1, AL121895.2, AAR2.
- chr20:40,004,216–47,188,844, 182 genes, copy number 5 (broad region; genes not listed).
- chr20:52,671,735–56,786,087, 54 genes, copy number 5: AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B, AURKA, CSTF1, CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P.
- chr20:57,168,753–57,620,576, 17 genes, copy number 5: BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1.
- chr20:61,252,261–62,762,771, 47 genes, copy number 5: CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2, TAF4, MIR1257, AL137077.1, MIR3195, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2.
- chr20:63,743,668–64,327,972, 37 genes, copy number 5: ZBTB46, AL121845.1, ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.

Autosomal genes at a single copy (total copy number 1): 8,307. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
